Somatic mutation profile of tumor specimen TCGA-BR-6452-01A (aliquot TCGA-BR-6452-01A-12D-1800-08) from TCGA case TCGA-BR-6452, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 78.9 years (28,827 days).
Specimen TCGA-BR-6452-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ca379de-06a8-45af-a319-6fd8955e2a4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6452-10A (Blood Derived Normal), aliquot TCGA-BR-6452-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/037a99e0-5010-4733-9b6e-c4076923c3cb

The open-access MAF lists 5,014 somatic variants for this specimen: 3,792 protein-altering or splice-affecting, 1,114 silent, 108 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,882, Silent 1,114, Frame Shift Del 526, Nonsense Mutation 127, Frame Shift Ins 118, Splice Site 76, Intron 40, Splice Region 34, RNA 31, In Frame Del 24, 3'UTR 12, 5'Flank 12.

Variants (750 of 5,014; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS1 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267606621, CM100179, COSV55746130, COSV55749637; ClinVar: pathogenic; called by mutect2, varscan2
- ABCC6 | c.3341G>A p.R1114H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs63750427, CM001040, CM030399; ClinVar: pathogenic; called by muse, mutect2
- AC011462.1 | c.219del p.R74Gfs*23 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, pindel
- AC068580.4 | c.268dup p.Q90Pfs*50 | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | catalogued as rs752612332; ClinVar: pathogenic; called by mutect2, varscan2
- ATM | c.4741dup p.I1581Nfs*5 | Frame Shift Ins (INS) | VAF 20/181 reads (11%) | catalogued as rs864622164; ClinVar: pathogenic; called by mutect2, pindel
- ATP7B | c.3556G>A p.G1186S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs786204547, CM139963, CM970146, CM980190, CS105442, COSV54439123, COSV54440767; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ATP7B | c.2743C>T p.Q915* | Nonsense Mutation (SNP) | VAF 9/112 reads (8%) | catalogued as rs1555288479, CD136097, COSV54439133; ClinVar: likely pathogenic; called by muse, mutect2
- COL4A1 | c.3715G>A p.G1239R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1085307709, CM150279, COSV65426539; ClinVar: pathogenic; called by muse, mutect2
- GANAB | c.2443C>T p.R815* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as rs1565088616, COSV55488854; ClinVar: pathogenic; called by muse, mutect2
- GMPPA | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 25/119 reads (21%) | catalogued as rs397518460, CM139393, COSV58006460; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNPTAB | c.2693del p.K898Sfs*13 | Frame Shift Del (DEL) | VAF 18/158 reads (11%) | catalogued as rs281864999, CD090839; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- HADHA | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 25/107 reads (23%) | catalogued as rs137852775, CM983469, COSV66106265; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HGF | c.495G>A p.S165= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs137853235, CS094308, COSV55948710; ClinVar: pathogenic; called by muse, varscan2
- IL17RA | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519079, COSV60053783; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIF5A | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs121434444, CM060295, COSV54051972; ClinVar: pathogenic / uncertain significance; called by mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 9/64 reads (14%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2D | c.15088C>T p.R5030C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555185875, CM138453, COSV56417619; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.1940dup p.P648Tfs*2 | Frame Shift Ins (INS) | VAF 18/60 reads (30%) | catalogued as rs770315135; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LTBP3 | c.2216del p.G739Afs*7 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs752375653, CD153951; ClinVar: pathogenic; called by mutect2, pindel
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, varscan2
- MKRN3 | c.482dup p.A162Gfs*15 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 18/134 reads (13%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.5167C>T p.R1723* | Nonsense Mutation (SNP) | VAF 23/108 reads (21%) | catalogued as rs121918267, CM042514, COSV56952714; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAFAH1B1 | c.910del p.S304Vfs*29 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | catalogued as rs587784292; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- POMGNT1 | c.1152+2T>C p.X384_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as rs1553163335, COSV64339996; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.97_99del p.I33del | In Frame Del (DEL) | VAF 8/63 reads (13%) | catalogued as rs1554893765; ClinVar: uncertain significance / likely pathogenic; called by pindel, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 22/110 reads (20%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RYR2 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs190140598, CM023669, COSV63663215; ClinVar: pathogenic; called by mutect2, varscan2
- SLX4 | c.425del p.G142Vfs*52 | Frame Shift Del (DEL) | VAF 19/88 reads (22%) | catalogued as rs757662453; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TCF4 | c.1146+1G>A p.X382_splice | Splice Site (SNP) | VAF 17/88 reads (19%) | catalogued as rs587784458, CS091867, COSV100609621; ClinVar: pathogenic; called by muse, mutect2
- TMEM106B | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554310600, COSV101188830, COSV67543986; ClinVar: likely pathogenic; called by muse, mutect2
- TOP3A | c.2271del p.R758Gfs*15 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | catalogued as rs752838075; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ZBTB18 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as rs1064792999, CM162492, COSV62396102; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.4323T>A p.D1441E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV59387495; called by muse, mutect2, varscan2
- A2M | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV59387508; called by muse, mutect2
- A2ML1 | c.922T>C p.Y308H | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.179); catalogued as rs1332175900, COSV55291532; called by muse, mutect2, varscan2
- AADACL2 | c.806A>C p.H269P | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62930693; called by muse, mutect2
- AADACL4 | c.666T>A p.Y222* | Nonsense Mutation (SNP) | VAF 12/195 reads (6%) | catalogued as COSV66106393; called by muse, mutect2
- AADAT | c.31A>G p.S11G | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV61787311; called by muse, mutect2
- ABCA12 | c.5778+2T>C p.X1926_splice (on ENST00000272895 / NM_173076.3; = p.X1608_splice on NM_015657.3) | Splice Site (SNP) | VAF 11/170 reads (6%) | catalogued as COSV55960894; called by muse, mutect2
- ABCA12 | c.4413T>A p.H1471Q (on ENST00000272895 / NM_173076.3; = p.H1153Q on NM_015657.3) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV55960912; called by muse, mutect2
- ABCA12 | c.3487T>C p.Y1163H (on ENST00000272895 / NM_173076.3; = p.Y845H on NM_015657.3) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55960952; called by muse, mutect2
- ABCA12 | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1053028479, COSV55960975; called by muse, mutect2
- ABCA13 | c.9230T>C p.I3077T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV71288916; called by muse, mutect2, varscan2
- ABCA3 | c.3873C>G p.Y1291* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV57054346; called by muse, mutect2, varscan2
- ABCA4 | c.1340A>G p.Q447R | Missense Mutation (SNP) | VAF 17/291 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV64674010; called by muse, mutect2
- ABCA5 | c.4198G>A p.A1400T | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV67017069; called by muse, mutect2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCA9 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs536079418, COSV60625488; called by muse, varscan2
- ABCB10 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV60621376; called by muse, mutect2, varscan2
- ABCB10 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60621386; called by muse, mutect2, varscan2
- ABCB11 | c.2795C>T p.A932V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as COSV55592212; called by muse, mutect2, varscan2
- ABCB6 | c.301dup p.A101Gfs*61 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs768732686; called by pindel, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC10 | c.2084A>G p.Y695C (on ENST00000372530 / NM_001198934.2; = p.Y667C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329195197, COSV55088592; called by muse, mutect2
- ABCC11 | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.167); catalogued as COSV62323440; called by muse, mutect2
- ABCC5 | c.3647C>T p.T1216M | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as rs1466487469, COSV55590907; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC5 | c.799A>T p.N267Y | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV55590912; called by muse, mutect2, varscan2
- ABCC6 | c.776A>G p.N259S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV52744395; called by muse, mutect2
- ABCC9 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV53973588; called by muse, mutect2, varscan2
- ABCD1 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.099); catalogued as rs1557052505, COSV54384796; called by muse, mutect2
- ABCD3 | c.1268T>G p.V423G | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV64643296; called by muse, mutect2, varscan2
- ABCD4 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs375098533, COSV53992663; called by mutect2, varscan2
- ABHD12 | c.295A>G p.K99E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV59286200; called by muse, mutect2, varscan2
- ABHD12B | c.531A>G p.R177= (on ENST00000337334 / NM_001206673.2; = p.R100= on NM_181533.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 11/139 reads (8%) | catalogued as COSV61569533; called by muse, mutect2
- AC004593.2 | c.1591A>G p.I531V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV56093178; called by muse, mutect2, varscan2
- AC005324.2 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV60886974; called by muse, mutect2
- AC008397.2 | c.1142A>G p.Y381C | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53207240; called by muse, mutect2
- AC009779.3 | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); catalogued as COSV57725544; called by muse, mutect2
- AC126283.2 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV67098793; called by muse, mutect2, varscan2
- ACACB | c.769del p.D257Ifs*17 | Frame Shift Del (DEL) | VAF 19/86 reads (22%) | catalogued as rs768607691; called by mutect2, pindel, varscan2
- ACACB | c.2144+1G>A p.X715_splice | Splice Site (SNP) | VAF 10/65 reads (15%) | catalogued as rs761541914, COSV58135773; called by muse, mutect2
- ACBD6 | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62573826; called by muse, mutect2, varscan2
- ACCS | c.1185G>T p.E395D | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV55458462; called by muse, mutect2, varscan2
- ACHE | c.1444A>G p.I482V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53818015; called by muse, mutect2, varscan2
- ACHE | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV53818034; called by muse, mutect2
- ACIN1 | c.3695G>T p.S1232I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.23); catalogued as COSV52976886; called by muse, mutect2, varscan2
- ACKR4 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.651); catalogued as COSV51442635; called by muse, mutect2
- ACOX2 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV57149236; called by mutect2, varscan2
- ACP3 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60486603; called by muse, mutect2
- ACP4 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54517059; called by muse, mutect2, varscan2
- ACP6 | c.533C>A p.A178D | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65077004; called by muse, varscan2
- ACSF2 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.043); catalogued as rs764360875, COSV51972702; called by mutect2, varscan2
- ACSS2 | c.1844T>A p.V615D | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53625038; called by muse, mutect2, varscan2
- ACTL6A | c.476+2T>C p.X159_splice | Splice Site (SNP) | VAF 17/256 reads (7%) | catalogued as COSV66999015; called by muse, mutect2
- ACTL7A | c.871A>G p.K291E | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.124); catalogued as COSV61776782; called by muse, mutect2
- ACTL7A | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV61776786; called by muse, mutect2, varscan2
- ACTR1B | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56704504; called by muse, mutect2, varscan2
- ACTR8 | c.1759A>T p.K587* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as COSV51636731; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 68/114 reads (60%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2B | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV61702435; called by muse, mutect2, varscan2
- ADAD1 | c.245T>A p.I82K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.135); catalogued as rs201675964, COSV56643895; called by mutect2, varscan2
- ADAM15 | c.2309del p.P770Lfs*35 (on ENST00000356955 / NM_207197.3; = p.P770Lfs*52 on NM_207194.3) | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs758144914; called by mutect2, pindel, varscan2
- ADAM18 | c.727A>T p.I243F | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55848276; called by muse, mutect2
- ADAM18 | c.1388A>T p.Y463F | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.405); catalogued as COSV55848283, COSV55848342; called by muse, mutect2
- ADAM19 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as COSV57430887; called by muse, mutect2, varscan2
- ADAM21 | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as COSV50795492; called by muse, mutect2
- ADAM7 | c.1898G>A p.C633Y | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51540727; called by mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS18 | c.1835A>G p.Q612R | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51413822; called by muse, mutect2
- ADAMTS18 | c.526T>A p.F176I | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV51413910; called by muse, mutect2
- ADAMTS2 | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV51080984; called by muse, mutect2, varscan2
- ADAMTS9 | c.3559C>T p.R1187* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV55782247; called by muse, varscan2
- ADAMTSL1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs866189730, COSV52825642; called by muse, mutect2
- ADAMTSL2 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1268212985, COSV63203828; called by muse, mutect2, varscan2
- ADAMTSL2 | c.830T>C p.F277S | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63204446; called by muse, mutect2, varscan2
- ADAMTSL4 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV55000428; called by muse, mutect2, varscan2
- ADAMTSL4 | c.745del p.L249Yfs*21 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as rs761084716; called by mutect2, pindel, varscan2
- ADAMTSL4 | c.2943+1G>A p.X981_splice | Splice Site (SNP) | VAF 11/53 reads (21%) | catalogued as rs1240172637, COSV55000463; called by muse, mutect2, varscan2
- ADAP2 | c.883-1G>T p.X295_splice | Splice Site (SNP) | VAF 6/50 reads (12%) | catalogued as rs778202064, COSV58296086; called by mutect2, varscan2
- ADAR | c.2021A>G p.E674G | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52716030; called by muse, mutect2, varscan2
- ADAR | c.1845del p.V616Sfs*45 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | catalogued as COSV52719476, COSV99426259; called by mutect2, pindel, varscan2
- ADARB2 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.988); catalogued as rs763862208, COSV67224603; called by muse, mutect2, varscan2
- ADCY1 | c.1765A>G p.T589A | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV52035465; called by muse, varscan2
- ADCY1 | c.2971G>A p.A991T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52029881, COSV52032579; called by muse, varscan2
- ADCY1 | c.3008T>C p.V1003A | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52035496; called by muse, varscan2
- ADCY2 | c.2231G>A p.C744Y | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57875204; called by muse, mutect2
- ADCY7 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV54267217; called by muse, mutect2, varscan2
- ADD1 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV53269708; called by muse, mutect2, varscan2
- ADD3 | c.378T>A p.D126E | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53322621; called by muse, mutect2
- ADD3 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1188455999, COSV53322629; called by muse, mutect2
- ADGRB1 | c.3775C>T p.P1259S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV60096093, COSV60097373; called by muse, mutect2
- ADGRB3 | c.2109G>C p.V703= | Splice Region (SNP) | VAF 8/99 reads (8%) | catalogued as COSV65398053; called by muse, mutect2
- ADGRD1 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs145630930, COSV55437665; called by muse, mutect2, varscan2
- ADGRE1 | c.1700G>A p.C567Y | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373945925; called by muse, mutect2, varscan2
- ADGRE1 | c.2567A>G p.K856R | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51676149; called by muse, varscan2
- ADGRF1 | c.1751T>C p.V584A | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as COSV51945792; called by muse, mutect2, varscan2
- ADGRF5 | c.2438T>G p.V813G | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV51934569, COSV99344710; called by muse, mutect2
- ADGRF5 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs768297112, COSV51930757; called by muse, mutect2, varscan2
- ADGRG4 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs896110034, COSV54951846, COSV54957798; called by muse, mutect2, varscan2
- ADGRG4 | c.8427T>A p.C2809* | Nonsense Mutation (SNP) | VAF 15/162 reads (9%) | catalogued as COSV54957443; called by muse, mutect2
- ADGRG6 | c.1343T>G p.V448G | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV51593153; called by muse, mutect2, varscan2
- ADGRG7 | c.2278T>C p.Y760H | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56297173; called by muse, mutect2
- ADGRG7 | c.2372A>T p.D791V | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV56297188; called by muse, mutect2
- ADGRL1 | c.3157G>A p.A1053T (on ENST00000340736 / NM_001008701.3; = p.A1048T on NM_014921.5) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1423061101, COSV61564934; called by muse, mutect2, varscan2
- ADGRL1 | c.203A>T p.D68V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61564941; called by muse, mutect2
- ADGRL2 | c.2317T>C p.F773L (on ENST00000370717 / NM_001366005.1; = p.F760L on NM_012302.4) | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV54669329; called by muse, mutect2
- ADGRL2 | c.2771C>T p.A924V (on ENST00000370717 / NM_001366005.1; = p.A911V on NM_012302.4) | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV54669370; called by muse, mutect2
- ADGRL2 | c.3266A>G p.K1089R (on ENST00000370717 / NM_001366005.1; = p.K1076R on NM_012302.4) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.488); catalogued as rs1023662572, COSV54669400; called by muse, mutect2, varscan2
- ADGRL2 | c.4189T>C p.S1397P (on ENST00000370717 / NM_001366005.1; = p.S1341P on NM_012302.4) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV54669440; called by muse, mutect2, varscan2
- ADGRV1 | c.11731G>T p.G3911* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV67986357; called by muse, mutect2
- ADH7 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV52921093; called by muse, mutect2, varscan2
- ADNP2 | c.2405A>T p.D802V | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51539206; called by muse, mutect2
- ADRA1A | c.104del p.G35Afs*12 | Frame Shift Del (DEL) | VAF 49/307 reads (16%) | catalogued as rs752308205; called by mutect2, pindel, varscan2
- ADRB1 | c.390C>A p.F130L | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as rs774348137, COSV65167915; called by mutect2, varscan2
- ADRB2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1156310662, COSV60005596; called by muse, mutect2
- ADSS1 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs769839836, COSV58273726; called by mutect2, varscan2
- AEBP2 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs1446877653, COSV56863849, COSV99857835; called by muse, mutect2, varscan2
- AFAP1 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV61795842; called by muse, mutect2
- AFAP1L1 | c.571T>A p.S191T | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57045491; called by muse, mutect2
- AFF2 | c.3889G>A p.V1297I | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.239); catalogued as rs782158550, COSV53977919; called by muse, mutect2, varscan2
- AFM | c.1056G>A p.A352= | Splice Region (SNP) | VAF 13/49 reads (27%) | catalogued as rs141061547; called by muse, mutect2, varscan2
- AFTPH | c.18T>G p.I6M | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53218385; called by muse, mutect2
- AFTPH | c.2257T>C p.Y753H | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53218423; called by muse, mutect2
- AGAP6 | c.1802G>A p.G601D (on ENST00000374056 / NM_001365867.1; = p.G624D on NM_001077665.2) | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV100929042; called by muse, mutect2
- AGBL2 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV54092525; called by muse, mutect2
- AGK | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.122); catalogued as rs863223892, COSV62594172; ClinVar: likely benign; called by muse, mutect2, varscan2
- AGO2 | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs760059271, COSV55047468; called by mutect2, varscan2
- AGRN | c.5582C>T p.A1861V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs138113721; called by mutect2, varscan2
- AHCYL1 | c.538T>C p.Y180H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV63208759; called by muse, mutect2, varscan2
- AHI1 | c.2450T>A p.I817N | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55628492; called by muse, mutect2
- AHI1 | c.1069T>C p.S357P | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV55628510; called by muse, mutect2
- AHNAK | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1307483240, COSV57215399; called by muse, varscan2
- AHNAK2 | c.16175C>A p.P5392Q | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60916820; called by muse, mutect2
- AHNAK2 | c.11165C>A p.P3722H | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs1410528874, COSV60916834; called by muse, mutect2
- AHNAK2 | c.9889G>A p.A3297T | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as COSV60916848; called by muse, mutect2
- AHNAK2 | c.7862C>T p.P2621L | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as rs760405983, COSV60916862; called by muse, mutect2
- AHNAK2 | c.2165A>G p.D722G | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV60916877; called by muse, mutect2, varscan2
- AKAP11 | c.412A>T p.I138F | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV50297336; called by muse, mutect2
- AKAP13 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV63459155; called by muse, mutect2
- AKAP17A | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58309975; called by muse, mutect2, varscan2
- AKAP3 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV57417186; called by muse, mutect2
- AKAP6 | c.3589-2A>G p.X1197_splice | Splice Site (SNP) | VAF 10/86 reads (12%) | catalogued as rs1566734757, COSV55215488; called by muse, mutect2, varscan2
- AKAP8L | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 19/277 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68473580; called by muse, mutect2
- AKAP9 | c.7440T>A p.D2480E (on ENST00000359028; = p.D2456E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV62347720; called by muse, mutect2
- AKIP1 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); catalogued as COSV55149009; called by muse, mutect2, varscan2
- AKR1D1 | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54337814; called by muse, varscan2
- AL121899.2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67350871; called by muse, mutect2
- AL669918.1 | c.2236A>T p.N746Y | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV71271034; called by muse, mutect2
- ALAD | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV52958428, COSV52959126; called by muse, mutect2, varscan2
- ALDH1A3 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as COSV60901856; called by muse, mutect2
- ALDH1L1 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs768309358, COSV56414649; called by muse, mutect2, varscan2
- ALDH6A1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.902); catalogued as COSV63246477; called by muse, mutect2, varscan2
- ALDH8A1 | c.61T>C p.C21R | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.356); catalogued as rs775919043, COSV55642092; called by mutect2, varscan2
- ALG10 | c.438del p.F146Lfs*20 | Frame Shift Del (DEL) | VAF 21/141 reads (15%) | catalogued as rs1163730964; called by mutect2, pindel, varscan2
- ALMS1 | c.6115C>A p.P2039T | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV52511155; called by muse, mutect2, varscan2
- ALMS1 | c.8107C>T p.P2703S | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV52511170; called by muse, varscan2
- ALOX5 | c.1966_1968del p.K656del | In Frame Del (DEL) | VAF 15/98 reads (15%) | catalogued as rs750469694; called by pindel, varscan2
- ALPK1 | c.3553A>G p.N1185D | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV51585681; called by muse, mutect2
- ALPK3 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1292786311, COSV51934090; called by muse, mutect2, varscan2
- ALPL | c.79A>G p.K27E | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66379923; called by muse, mutect2
- ALS2 | c.3523T>C p.Y1175H | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV51887799; called by muse, mutect2
- ALS2CL | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.321); catalogued as COSV59671724; called by mutect2, varscan2
- AMD1 | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64387441; called by muse, mutect2
- AMER3 | c.705T>G p.C235W | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58467178; called by muse, mutect2, varscan2
- AMIGO3 | c.1181G>A p.G394D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV57538804; called by muse, mutect2
- AMIGO3 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV57538812; called by mutect2, varscan2
- AMY2B | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 19/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63715438; called by muse, mutect2
- ANAPC2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as COSV58807619; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 31/146 reads (21%) | catalogued as rs34047276; called by mutect2, varscan2
- ANK2 | c.11620A>G p.M3874V | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as COSV52163844; called by muse, mutect2, varscan2
- ANKFN1 | c.760A>G p.R254G | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV59448763; called by muse, mutect2
- ANKLE1 | c.1082del p.P361Hfs*30 (on ENST00000394458; = p.P307Hfs*30 on NM_152363.6) | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | catalogued as rs778834689; called by mutect2, pindel, varscan2
- ANKLE2 | c.1085A>G p.N362S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV61709713; called by muse, mutect2
- ANKRD13A | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55675853; called by muse, mutect2, varscan2
- ANKRD17 | c.6676A>T p.T2226S | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV58220793; called by muse, mutect2
- ANKRD17 | c.2593A>T p.I865F | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV58220828; called by muse, mutect2
- ANKRD36B | c.901A>G p.S301G | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs754984562, COSV51532799; called by mutect2, varscan2
- ANKRD50 | c.3521G>A p.R1174Q | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs753523756, COSV72385614; called by muse, mutect2, varscan2
- ANKRD55 | c.1483A>G p.K495E | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.01); catalogued as COSV61947097; called by muse, mutect2, varscan2
- ANKS1A | c.1753A>G p.T585A | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV64461098; called by muse, mutect2
- ANO1 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.49); catalogued as rs763424037, COSV60285302; called by muse, mutect2
- ANO2 | c.1628C>T p.A543V (on ENST00000356134 / NM_001278597.3; = p.A547V on NM_001278596.3) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV59025458; called by muse, mutect2, varscan2
- ANO4 | c.442C>A p.Q148K (on ENST00000392977 / NM_001286615.2; = p.Q113K on NM_178826.4) | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs746948652, COSV54597531; called by muse, mutect2, varscan2
- ANTXR1 | c.468T>A p.D156E | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV58014266; called by muse, mutect2, varscan2
- ANTXR1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1459161935, COSV58014293; called by muse, mutect2, varscan2
- ANXA10 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); catalogued as COSV63739138; called by muse, mutect2, varscan2
- AOC1 | c.421A>G p.R141G | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62868939; called by muse, varscan2
- AP002748.5 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 7/114 reads (6%) | catalogued as COSV59149156; called by muse, mutect2
- AP1G2 | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1427295596; called by muse, mutect2
- AP2A2 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as rs1015727759, COSV59960639; called by muse, mutect2
- AP3D1 | c.3374A>G p.N1125S | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV61428922; called by muse, mutect2
- AP3M2 | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs984962856, COSV51529106; called by muse, mutect2, varscan2
- AP4B1 | c.21G>T p.E7D | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV56725145, COSV99870639; called by muse, mutect2, varscan2
- AP4E1 | c.2216A>T p.E739V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as COSV55917366; called by mutect2, varscan2
- AP5Z1 | c.1163T>A p.V388D | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV62242092; called by muse, mutect2
- APC | c.7649A>T p.E2550V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57347760; called by muse, mutect2
- APIP | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV53507084; called by muse, mutect2, varscan2
- APLNR | c.661T>C p.Y221H | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57242835; called by muse, mutect2
- APOB | c.13345C>A p.Q4449K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV51937657; called by muse, mutect2, varscan2
- APOB | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs886039827, COSV51937726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBEC1 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as rs1251310652, COSV57549127; called by muse, mutect2
- APOBEC3B | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.048); catalogued as COSV59841135; called by muse, mutect2, varscan2
- APOL2 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV50772216; called by muse, mutect2, varscan2
- APOL6 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV68749532; called by muse, mutect2, varscan2
- AQP11 | c.254_256del p.F85del | In Frame Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs747275160; called by pindel, varscan2
- ARAF | c.873+2T>C p.X291_splice | Splice Site (SNP) | VAF 6/70 reads (9%) | catalogued as COSV51692964; called by muse, mutect2
- ARFGAP3 | c.896del p.N299Mfs*22 | Frame Shift Del (DEL) | VAF 35/166 reads (21%) | catalogued as rs774441374, COSV54310368; called by mutect2, varscan2
- ARFGEF2 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV64212656; called by mutect2, varscan2
- ARFGEF2 | c.4111T>C p.W1371R | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64212661; called by muse, mutect2
- ARHGAP21 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100255803; called by muse, mutect2, varscan2
- ARHGAP24 | c.1454G>A p.G485D (on ENST00000395184 / NM_001025616.3; = p.G392D on NM_031305.3) | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV51989574; called by muse, mutect2
- ARHGAP25 | c.1379G>A p.S460N (on ENST00000409202 / NM_001007231.3; = p.S452N on NM_014882.3) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV54903052; called by muse, mutect2
- ARHGAP31 | c.135A>G p.I45M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757179237, COSV51793598; called by mutect2, varscan2
- ARHGAP31 | c.1085G>C p.G362A | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV51793607; called by muse, mutect2
- ARHGAP33 | c.1799del p.G600Afs*32 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | catalogued as COSV50135591, COSV50193304; called by mutect2, pindel, varscan2
- ARHGAP35 | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV68331755; called by muse, mutect2, varscan2
- ARHGEF10 | c.1003A>T p.I335F (on ENST00000398564; = p.I310F on NM_014629.4) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV50652446; called by muse, mutect2
- ARHGEF10 | c.1843C>T p.R615C (on ENST00000398564; = p.R590C on NM_014629.4) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs141069028; called by muse, mutect2, varscan2
- ARHGEF10L | c.3242G>A p.G1081D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51433477; called by mutect2, varscan2
- ARHGEF11 | c.2486C>T p.A829V | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.151); catalogued as rs778249084, COSV59354898; called by muse, mutect2, varscan2
- ARHGEF11 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs780005478, COSV59353176; called by muse, varscan2
- ARHGEF15 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV62725345; called by muse, mutect2, varscan2
- ARHGEF16 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV65682169; called by muse, mutect2
- ARHGEF19 | c.1969A>C p.S657R | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as COSV54616909; called by muse, mutect2
- ARHGEF25 | c.92dup p.R32Tfs*2 | Frame Shift Ins (INS) | VAF 14/52 reads (27%) | catalogued as rs748506876; called by mutect2, varscan2
- ARHGEF26 | c.714C>G p.N238K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV62846941; called by muse, mutect2
- ARHGEF37 | c.1011A>T p.Q337H | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV61368870; called by muse, mutect2, varscan2
- ARHGEF7 | c.1430T>C p.L477P (on ENST00000375741 / NM_001113511.2; = p.L299P on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54539429; called by muse, mutect2
- ARHGEF9 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53638920; called by muse, mutect2, varscan2
- ARID1A | c.2402del p.G801Vfs*32 | Frame Shift Del (DEL) | VAF 11/113 reads (10%) | catalogued as COSV61388445; called by mutect2, pindel
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 58/130 reads (45%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID2 | c.1100A>T p.D367V | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57604913; called by muse, varscan2
- ARL6IP1 | c.386T>G p.L129R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs372691774; called by mutect2, varscan2
- ARL9 | c.466T>A p.S156T (on ENST00000640821 / NM_001363794.2; = p.S14T on NM_206919.2) | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.142); catalogued as rs1283942738, COSV63991305; called by muse, mutect2
- ARL9 | c.649A>T p.I217F (on ENST00000640821 / NM_001363794.2; = p.I75F on NM_206919.2) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100781248; called by mutect2, varscan2
- ARMCX1 | c.872T>C p.V291A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65705228; called by mutect2, varscan2
- ARPP19 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV51119343; called by muse, mutect2, varscan2
- ARSG | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs758304459, COSV50930176; called by muse, mutect2, varscan2
- ART1 | c.735del p.F246Lfs*6 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | catalogued as rs762428866, COSV99167258; called by mutect2, pindel, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASAP3 | c.2528A>G p.Y843C | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as COSV60875047; called by muse, mutect2
- ASB12 | c.52A>G p.I18V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV62857032; called by muse, mutect2, varscan2
- ASB14 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV67467190, COSV67467249; called by muse, mutect2, varscan2
- ASB17 | c.530del p.N177Tfs*7 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs749460467; called by mutect2, pindel, varscan2
- ASB6 | c.1222T>C p.Y408H | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV52965063; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 34/155 reads (22%) | catalogued as rs761154268; called by mutect2, varscan2
- ASH1L | c.1580G>A p.C527Y | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as COSV64208543; called by muse, varscan2
- ASH2L | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV51699810; called by mutect2, varscan2
- ASMT | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs189062200, COSV101172411; called by muse, mutect2, varscan2
- ASNS | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as rs398122975, CM1310819, COSV51552621; called by mutect2, varscan2
- ASPM | c.6488A>G p.Y2163C | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54130685; called by muse, mutect2
- ASPM | c.2929C>T p.R977C | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750015604, COSV54130724; called by muse, mutect2, varscan2
- ASXL3 | c.2311T>A p.S771T | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); catalogued as COSV52467555; called by muse, mutect2
- ASXL3 | c.3702T>A p.N1234K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as COSV52467572; called by muse, mutect2
- ATF6 | c.967T>A p.S323T | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV63407773; called by muse, mutect2
- ATG10 | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV56426605; called by muse, mutect2, varscan2
- ATG2B | c.5246C>T p.T1749I | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.796); catalogued as rs563718339, COSV55890564; called by muse, mutect2, varscan2
- ATG4A | c.984A>C p.K328N | Missense Mutation (SNP) | VAF 23/343 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV57867866; called by muse, mutect2
- ATIC | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs1339955704, COSV52693364; called by muse, varscan2
- ATM | c.7193A>G p.Y2398C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53747654; called by muse, mutect2, varscan2
- ATMIN | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as COSV100214766, COSV55146306; called by muse, mutect2, varscan2
- ATN1 | c.2831A>G p.D944G | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as COSV63111209; called by mutect2, varscan2
- ATP10A | c.1207A>G p.T403A | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV63518173; called by muse, mutect2
- ATP11A | c.3332A>G p.K1111R | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV52112938; called by muse, mutect2
- ATP11B | c.2816T>C p.V939A | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV60029189; called by muse, mutect2
- ATP12A | c.1999G>A p.V667M | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV54517192; called by muse, mutect2, varscan2
- ATP13A1 | c.3017A>G p.Y1006C | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52286536; called by muse, mutect2, varscan2
- ATP13A1 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.073); catalogued as rs200186450, COSV52286567; called by muse, mutect2, varscan2
- ATP13A3 | c.1904T>C p.M635T | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV55461932; called by muse, mutect2, varscan2
- ATP13A4 | c.509T>C p.L170S | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55069947; called by muse, mutect2, varscan2
- ATP13A5 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs779155800, COSV60869939; called by mutect2, varscan2
- ATP1A1 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV55191560; called by muse, mutect2, varscan2
- ATP2B3 | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54848929; called by muse, mutect2
- ATP2C1 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1341543519, COSV60757165; called by muse, varscan2
- ATP2C2 | c.1237G>T p.G413W | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52296702; called by mutect2, varscan2
- ATP5F1A | c.1483T>C p.Y495H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as rs1156524484, COSV56360596; called by mutect2, varscan2
- ATP5PF | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV53167142; called by muse, mutect2, varscan2
- ATP6AP2 | c.424T>C p.S142P | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV65797750; called by muse, mutect2
- ATP6V0B | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758360388, COSV52543616; called by muse, mutect2, varscan2
- ATP6V0E2 | c.227T>C p.V76A (on ENST00000425642; = p.V125A on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1335810015, COSV101374569; called by muse, mutect2, varscan2
- ATP6V1H | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); catalogued as rs1178321403, COSV62218532; called by muse, varscan2
- ATP7A | c.1403A>T p.N468I | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV58447073; called by muse, mutect2, varscan2
- ATP7B | c.1789G>A p.V597I | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs760501309, CM133426, COSV54439147, COSV54443836; called by muse, mutect2, varscan2
- ATP8B3 | c.2015G>T p.R672M | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV59543286; called by muse, mutect2, varscan2
- ATP8B4 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52716539; called by muse, mutect2, varscan2
- ATPAF1 | c.910A>T p.M304L (on ENST00000574428; = p.M327L on NM_022745.4) | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV61305087; called by muse, mutect2
- ATPAF1 | c.451G>A p.E151K (on ENST00000574428; = p.E174K on NM_022745.4) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100236000, COSV61304494; called by muse, varscan2
- ATR | c.6661A>G p.K2221E | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV63387001; called by muse, mutect2
- ATRNL1 | c.3202A>T p.I1068F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.079); catalogued as COSV58090707; called by muse, mutect2, varscan2
- ATXN2L | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV57371451; called by muse, mutect2, varscan2
- ATXN3L | c.854A>T p.D285V | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV66075758; called by muse, mutect2
- AXDND1 | c.911A>G p.D304G | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV62643292; called by muse, mutect2
- B3GALT4 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as COSV65851654; called by muse, mutect2, varscan2
- B3GNT8 | c.1087A>G p.T363A | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54197420; called by muse, mutect2, varscan2
- BACH2 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV57594167; called by muse, mutect2, varscan2
- BACH2 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV57594181; called by muse, varscan2
- BAMBI | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV65003070; called by muse, mutect2, varscan2
- BANF1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56463664; called by muse, mutect2
- BAZ2B | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV58601863; called by mutect2, varscan2
- BBOX1 | c.1004-1G>T p.X335_splice | Splice Site (SNP) | VAF 9/69 reads (13%) | catalogued as COSV54191363; called by muse, mutect2
- BBS9 | c.2454A>T p.R818S (on ENST00000242067 / NM_001348036.1; = p.R778S on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54170305; called by muse, mutect2
- BCAN | c.1243G>T p.G415* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | catalogued as COSV100228462, COSV61257115; called by mutect2, varscan2
- BCAR3 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as rs1320491741, COSV53075561; called by muse, mutect2, varscan2
- BCAS1 | c.1399A>G p.K467E | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV65086513; called by muse, mutect2, varscan2
- BCAS3 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV66774834; called by muse, mutect2
- BCHE | c.1078T>C p.Y360H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV52257344; called by mutect2, varscan2
- BCL11B | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.964); catalogued as rs770333002, COSV61735869; called by mutect2, varscan2
- BCL2L13 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100456153; called by muse, mutect2, varscan2
- BCL6B | c.546del p.S183Vfs*20 | Frame Shift Del (DEL) | VAF 30/135 reads (22%) | catalogued as COSV53426596; called by mutect2, pindel, varscan2
- BCORL1 | c.3749T>C p.F1250S | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV54397287; called by muse, mutect2
- BCORL1 | c.4711T>G p.F1571V | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.389); catalogued as COSV54397302; called by muse, mutect2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | catalogued as rs768244116; called by mutect2, pindel
- BDP1 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751018376, COSV62430327; called by muse, mutect2, varscan2
- BEND6 | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV66069118; called by mutect2, varscan2
- BEX1 | c.80T>A p.V27D | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV104425219, COSV65580244; called by muse, mutect2
- BICC1 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV54064103; called by muse, mutect2, varscan2
- BICD2 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs912659311, COSV63549183; called by muse, mutect2, varscan2
- BICD2 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs774714446, COSV63548838; called by mutect2, varscan2
- BIN3 | c.338del p.K113Sfs*13 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs776003776; called by mutect2, varscan2
- BIRC2 | c.1573A>G p.K525E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV99926536; called by muse, mutect2, varscan2
- BIRC6 | c.6290C>T p.S2097F | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV70199871; called by muse, mutect2
- BLK | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs201698258, COSV52052388; called by mutect2, varscan2
- BLVRA | c.182A>G p.D61G | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55514516; called by muse, mutect2, varscan2
- BMP10 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54895463; called by muse, mutect2, varscan2
- BMP2 | c.953del p.P318Rfs*20 | Frame Shift Del (DEL) | VAF 17/109 reads (16%) | catalogued as COSV66577125; called by mutect2, pindel, varscan2
- BMP3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as rs765583405, COSV51085712; called by mutect2, varscan2
- BMP4 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as COSV55416169; called by muse, mutect2, varscan2
- BMX | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59591563; called by muse, mutect2, varscan2
- BMX | c.1601A>G p.H534R | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59591573; called by muse, mutect2
- BNC1 | c.2069G>T p.R690M | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV61757625; called by muse, mutect2, varscan2
- BOC | c.2239G>T p.G747C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56351594; called by muse, mutect2, varscan2
- BRD3 | c.236del p.N79Tfs*12 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | catalogued as COSV57706028; called by mutect2, pindel, varscan2
- BRD3 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV57704006; called by muse, varscan2
- BRD8 | c.1439T>C p.V480A (on ENST00000254900 / NM_139199.2; = p.V553A on NM_006696.4) | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.501); catalogued as COSV50150431; called by muse, mutect2
- BRDT | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 8/103 reads (8%) | catalogued as rs1426040148, COSV61771205; called by muse, mutect2
- BRF2 | c.418A>C p.T140P | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV55104028; called by muse, mutect2
- BRWD1 | c.287G>C p.S96T | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as COSV58122872; called by muse, mutect2, varscan2
- BRWD3 | c.3211C>T p.Q1071* | Nonsense Mutation (SNP) | VAF 61/233 reads (26%) | catalogued as COSV64748834; called by muse, mutect2, varscan2
- BSN | c.6175C>T p.R2059W | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56519274; called by muse, mutect2
- BSN | c.8947A>T p.I2983F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56519290; called by muse, mutect2
- BTAF1 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56434691; called by muse, mutect2, varscan2
- BTBD11 | c.2131G>A p.G711S (on ENST00000280758 / NM_001018072.2; = p.G248S on NM_001017523.2) | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55025398; called by muse, mutect2, varscan2
- BTBD6 | c.1394C>T p.S465L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.61); catalogued as rs587764427, COSV59268478; called by muse, mutect2, varscan2
- BTK | c.1880A>G p.Y627C | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV58120330, COSV58120829; called by muse, mutect2
- BZW1 | c.1184A>C p.E395A | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV63349757; called by muse, mutect2, varscan2
- C10orf62 | c.317T>A p.I106N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV65705285; called by muse, mutect2
- C12orf4 | c.1590T>A p.Y530* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV54207346; called by muse, mutect2
- C14orf39 | c.1655A>C p.D552A | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58782370; called by muse, mutect2, varscan2
- C16orf70 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV54627469; called by muse, varscan2
- C17orf75 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.173); catalogued as COSV56752915; called by muse, mutect2, varscan2
- C17orf80 | c.1636A>G p.N546D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.318); catalogued as COSV52146850; called by mutect2, varscan2
- C1QBP | c.415A>G p.I139V | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.03); catalogued as COSV56709340; called by muse, mutect2
- C1orf162 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.29); catalogued as COSV59059221; called by muse, mutect2
- C1orf198 | c.538G>T p.G180C | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV64175462; called by muse, varscan2
- C2orf16 | c.775A>G p.T259A | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV101284337; called by muse, mutect2
- C2orf42 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs139242568; called by muse, varscan2
- C2orf42 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52450501; called by muse, varscan2
- C3 | c.1601A>G p.Y534C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM131617, COSV55573925; called by muse, mutect2
- C3AR1 | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV50819233; called by muse, mutect2, varscan2
- C3orf20 | c.2367del p.K790Sfs*9 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | catalogued as rs762124133; called by mutect2, pindel, varscan2
- C3orf38 | c.436T>C p.C146R | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59628142; called by muse, mutect2
- C4A | c.3215G>A p.R1072Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs771330838, COSV71177696; called by muse, varscan2
- C4A | c.3229T>C p.W1077R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71177873; called by muse, varscan2
- C5 | c.1372T>A p.S458T | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); catalogued as COSV56327965; called by muse, mutect2
- C6orf118 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.062); catalogued as COSV57815462; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- C9 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546890218, COSV54674723; called by muse, mutect2, varscan2
- CA4 | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV56281643; called by muse, mutect2, varscan2
- CAAP1 | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61700835; called by muse, mutect2, varscan2
- CABP5 | c.433del p.R145Gfs*24 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs769959570, COSV99506527; called by mutect2, pindel, varscan2
- CABS1 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs1355217877, COSV56733746; called by muse, mutect2, varscan2
- CACNA1B | c.3890C>T p.A1297V | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53128238; called by muse, mutect2
- CACNA1C | c.3679G>A p.V1227I | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs373124557; ClinVar: uncertain significance; called by mutect2, varscan2
- CACNA1D | c.964A>G p.N322D | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as COSV55448964; called by muse, mutect2
- CACNA1D | c.2021G>A p.G674D (on ENST00000350061 / NM_001128840.3; = p.G694D on NM_000720.4) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55447067, COSV99052036; called by muse, varscan2
- CACNA1G | c.3919C>T p.R1307C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61729183; called by muse, mutect2, varscan2
- CACNA1I | c.2524T>C p.F842L | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV100361999, COSV60809896; called by muse, mutect2
- CACNA1I | c.3869C>T p.P1290L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1468688369, COSV60800974, COSV60809917; called by muse, mutect2, varscan2
- CACNA2D1 | c.948del p.V317Cfs*2 | Frame Shift Del (DEL) | VAF 28/134 reads (21%) | catalogued as COSV100666438; called by mutect2, pindel, varscan2
- CACNB2 | c.1259A>G p.N420S (on ENST00000324631 / NM_201596.3; = p.N365S on NM_000724.4) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as COSV56627386; called by muse, mutect2, varscan2
- CACNG7 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs1178914944, COSV55814692; called by muse, mutect2, varscan2
- CACTIN | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); catalogued as COSV50268666; called by muse, mutect2, varscan2
- CAGE1 | c.800C>T p.T267I (on ENST00000512086; = p.T131I on NM_205864.3) | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.387); catalogued as COSV57077835; called by muse, mutect2
- CALML5 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs1349085552, COSV66702564; called by muse, mutect2, varscan2
- CAMK2B | c.740del p.N247Tfs*7 | Frame Shift Del (DEL) | VAF 15/122 reads (12%) | catalogued as COSV99033778; called by mutect2, pindel, varscan2
- CAMK4 | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs762274428, COSV56672156; called by mutect2, varscan2
- CAMSAP1 | c.3232C>T p.P1078S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV56723229, COSV56727137; called by muse, mutect2, varscan2
- CAMTA1 | c.3401G>A p.R1134H | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs370253741, COSV57922957; called by muse, mutect2, varscan2
- CAMTA1 | c.3685T>G p.S1229A | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV57903782; called by muse, mutect2
- CARD11 | c.3110T>A p.I1037N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV67799555; called by muse, mutect2, varscan2
- CARD6 | c.2261G>A p.G754D | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV54566523; called by muse, mutect2
- CARMIL1 | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.6); catalogued as rs775025651, COSV61518139; called by mutect2, varscan2
- CARMIL3 | c.4015del p.L1339* | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as rs1167529280; called by mutect2, pindel, varscan2
- CARS1 | c.803T>C p.V268A | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53455242; called by muse, mutect2
- CASP1 | c.614del p.N205Ifs*7 (on ENST00000436863 / NM_033292.4; = p.N184Ifs*7 on NM_001223.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/111 reads (11%) | catalogued as rs746543598, COSV62056860; called by mutect2, varscan2
- CASP10 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV53778660; called by muse, mutect2, varscan2
- CASP4 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67744482; called by muse, mutect2, varscan2
- CASP8AP2 | c.5323A>G p.K1775E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.602); catalogued as COSV52747383; called by mutect2, varscan2
- CASP9 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751589736, COSV61601561; called by mutect2, varscan2
- CASR | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV56138034; called by muse, mutect2, varscan2
- CASZ1 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs761216432, COSV59732506; called by mutect2, varscan2
- CATSPER3 | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV50946788; called by muse, mutect2
- CBLN1 | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV54654151; called by mutect2, varscan2
- CBX1 | c.149A>G p.N50S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV56681968; called by muse, mutect2
- CBX3 | c.42del p.K14Nfs*23 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as COSV61761904; called by mutect2, pindel
- CBX8 | c.106T>C p.S36P | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV53936594; called by muse, mutect2, varscan2
- CC2D1A | c.2786G>T p.R929M | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54308772; called by muse, mutect2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 36/245 reads (15%) | catalogued as rs756536005; called by mutect2, pindel, varscan2
- CCDC141 | c.3434C>G p.A1145G | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV55374400; called by muse, varscan2
- CCDC144A | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as COSV60698451, COSV60698573; called by muse, mutect2, varscan2
- CCDC150 | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1432123148, COSV55874873; called by muse, mutect2, varscan2
- CCDC170 | c.704T>C p.L235P | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262434063, COSV53341359; called by muse, mutect2
- CCDC174 | c.628A>G p.R210G | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV57981148; called by muse, mutect2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC180 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.23); catalogued as COSV63830880; called by muse, mutect2
- CCDC181 | c.1258A>T p.K420* (on ENST00000367806 / NM_001300969.1; = p.K419* on NM_021179.2) | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as rs1048688163, COSV61392567, COSV61393785; called by muse, mutect2, varscan2
- CCDC25 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV62958811; called by muse, mutect2
- CCDC33 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.164); catalogued as COSV58352517; called by muse, mutect2, varscan2
- CCDC57 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as rs776885930, COSV66434224; called by muse, mutect2, varscan2
- CCDC58 | c.285T>A p.D95E | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV52247074; called by muse, mutect2
- CCDC60 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59544646; called by muse, mutect2
- CCDC62 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53434023; called by muse, mutect2, varscan2
- CCDC63 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV57528761; called by muse, mutect2, varscan2
- CCDC73 | c.2683del p.T895Lfs*8 | Frame Shift Del (DEL) | VAF 36/173 reads (21%) | catalogued as rs764792181; called by mutect2, pindel, varscan2
- CCDC80 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52817222; called by muse, mutect2
- CCDC81 | c.99del p.N34Mfs*6 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs1565758547; called by mutect2, pindel, varscan2
- CCDC81 | c.569T>C p.V190A (on ENST00000445632 / NM_001156474.2; = p.V100A on NM_021827.4) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs752000386, COSV53578817; called by mutect2, varscan2
- CCDC87 | c.2518A>T p.T840S | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV59578816, COSV59579232; called by muse, mutect2, varscan2
- CCDC88A | c.2572A>T p.K858* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as COSV55062565; called by muse, mutect2, varscan2
- CCDC88C | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as rs1201659596, COSV66238638; called by muse, mutect2, varscan2
- CCDC92 | c.582dup p.K195Qfs*25 | Frame Shift Ins (INS) | VAF 8/78 reads (10%) | catalogued as rs771590551; called by mutect2, pindel
- CCM2L | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs778563139, COSV52950492, COSV99395164; called by muse, mutect2, varscan2
- CCNE1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs918480017, COSV52904615; called by muse, mutect2
- CCNJ | c.911T>C p.V304A | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV56443129; called by muse, varscan2
- CCNL2 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.965); catalogued as rs746945804, COSV68766681; called by muse, mutect2, varscan2
- CCPG1 | c.1573T>A p.F525I | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51241972; called by muse, mutect2, varscan2
- CCR2 | c.347T>A p.F116Y | Missense Mutation (SNP) | VAF 38/459 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV52748898; called by muse, mutect2
- CCT6A | c.1384A>T p.T462S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV99303232; called by muse, mutect2, varscan2
- CD101 | c.1841C>T p.T614M | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs752908226, COSV56718371; called by muse, mutect2, varscan2
- CD109 | c.1497+2T>C p.X499_splice | Splice Site (SNP) | VAF 9/72 reads (13%) | catalogued as COSV54650118; called by muse, varscan2
- CD163 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63132974; called by muse, mutect2
- CD276 | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59204008; called by mutect2, varscan2
- CD300LB | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58725802; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | catalogued as rs781937995, COSV99163893; called by pindel, varscan2
- CD6 | c.1400C>A p.P467H | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV57839115; called by muse, mutect2, varscan2
- CD79A | c.364T>C p.Y122H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55738731; called by muse, varscan2
- CD93 | c.838del p.D280Mfs*19 | Frame Shift Del (DEL) | VAF 25/142 reads (18%) | catalogued as rs1276928429, COSV55666935; called by mutect2, pindel, varscan2
- CDADC1 | c.388T>C p.S130P | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51911774; called by muse, mutect2, varscan2
- CDAN1 | c.2576C>T p.P859L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs370476233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDAN1 | c.1317T>A p.N439K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51162518; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC25A | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs746603686, COSV56770780; called by muse, varscan2
- CDC42BPB | c.680A>G p.D227G | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV63475214; called by muse, mutect2, varscan2
- CDC42EP3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs201549749; called by muse, mutect2, varscan2
- CDC5L | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65176171; called by muse, mutect2, varscan2
- CDC73 | c.143A>G p.E48G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV66467198, COSV66467873; called by mutect2, varscan2
- CDCA2 | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV55340310; called by muse, mutect2
- CDH1 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs876660560, COSV55733625; ClinVar: uncertain significance; called by muse, mutect2
- CDH10 | c.2051A>T p.K684I | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.14); catalogued as COSV52582798; called by muse, mutect2, varscan2
- CDH12 | c.458T>A p.I153N | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66409131; called by muse, mutect2, varscan2
- CDH13 | c.1144A>G p.N382D | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51824835; called by muse, mutect2, varscan2
- CDH19 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV50960285; called by muse, mutect2, varscan2
- CDH2 | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52281877; called by muse, mutect2, varscan2
- CDH20 | c.4T>C p.W2R | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV53010746; called by muse, mutect2, varscan2
- CDH20 | c.1268T>A p.I423N | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV53010758; called by muse, mutect2, varscan2
- CDH23 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753985914; called by mutect2, varscan2
- CDH5 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1335606003, COSV58515607; called by muse, mutect2, varscan2
- CDH6 | c.1061T>G p.V354G | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV54070882; called by muse, mutect2
- CDHR1 | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV60562919; called by muse, mutect2
- CDHR1 | c.1977G>T p.K659N | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV60562933; called by muse, mutect2
- CDHR2 | c.2128+2T>C p.X710_splice | Splice Site (SNP) | VAF 5/69 reads (7%) | catalogued as COSV56139627; called by muse, mutect2
- CDK14 | c.298T>C p.C100R (on ENST00000380050 / NM_001287135.2; = p.C82R on NM_012395.3) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56036483; called by muse, mutect2
- CDK18 | c.872T>C p.I291T (on ENST00000506784 / NM_212503.3; = p.I261T on NM_002596.4) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV63727654; called by muse, mutect2, varscan2
- CDK5RAP1 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59427044; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2858G>A p.R953H | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs149193447, COSV62574678; called by muse, mutect2, varscan2
- CDK6 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.319); catalogued as rs902137115, COSV56008604; called by muse, mutect2, varscan2
- CDK6 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.794); catalogued as rs761377867, COSV56008615; called by mutect2, varscan2
- CDKL5 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV66111570; called by muse, mutect2
- CDX2 | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV66829537; called by muse, mutect2, varscan2
- CDYL | c.335G>A p.R112H (on ENST00000328908 / NM_001368125.1; = p.R58H on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs200111001; called by mutect2, varscan2
- CEACAM1 | c.1394A>G p.D465G | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV50728015; called by muse, mutect2
- CEACAM16 | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69187112; called by muse, varscan2
- CEBPZ | c.2446A>G p.R816G | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52206557; called by muse, mutect2
- CEBPZ | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs768232491, COSV50017702; called by muse, mutect2, varscan2
- CEBPZ | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758511317, COSV104374023, COSV50017706; called by mutect2, varscan2
- CELSR2 | c.2863C>A p.Q955K | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.953); catalogued as COSV54772938; called by muse, mutect2, varscan2
- CEMIP2 | c.3300A>T p.E1100D | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65484600; called by muse, mutect2
- CENPE | c.2428T>C p.S810P | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV54382054; called by muse, mutect2
- CENPF | c.4592T>C p.L1531P | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as COSV65275378; called by muse, mutect2, varscan2
- CENPL | c.364dup p.S122Ffs*29 | Frame Shift Ins (INS) | VAF 12/122 reads (10%) | catalogued as rs1359644753; called by mutect2, pindel
- CENPQ | c.68del p.K23Rfs*17 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | catalogued as COSV100225616; called by mutect2, pindel, varscan2
- CEP126 | c.395-2A>G p.X132_splice | Splice Site (SNP) | VAF 6/55 reads (11%) | catalogued as COSV54825704; called by mutect2, varscan2
- CEP162 | c.757A>G p.N253D | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1562076065, COSV57620302; called by muse, mutect2
- CEP192 | c.5746C>T p.R1916C | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs368997588; called by muse, mutect2, varscan2
- CEP20 | c.53del p.K18Rfs*4 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as rs746479678; called by mutect2, pindel, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 46/176 reads (26%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP350 | c.3611G>A p.R1204H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV62603410; called by muse, mutect2, varscan2
- CEP57L1 | c.1337A>G p.N446S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV61244897; called by mutect2, varscan2
- CEP63 | c.1597A>T p.M533L | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59676720; called by muse, mutect2, varscan2
- CEP72 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs368269218; called by muse, mutect2, varscan2
- CEP76 | c.406T>A p.F136I | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV50866885; called by muse, mutect2, varscan2
- CERK | c.1428del p.K477Rfs*74 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | catalogued as rs761362852; called by pindel, varscan2
- CERK | c.1381A>G p.T461A | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV53451567; called by muse, varscan2
- CERKL | c.1286G>A p.S429N (on ENST00000339098 / NM_001030311.2; = p.S403N on NM_201548.5) | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.062); catalogued as COSV59208240; called by muse, varscan2
- CERS6 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.174); catalogued as COSV59830743; called by muse, mutect2
- CES5A | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.49); catalogued as COSV51866789; called by muse, mutect2, varscan2
- CETN2 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as COSV64744102; called by muse, mutect2, varscan2
- CETP | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52362821; called by mutect2, varscan2
- CFAP157 | c.200_202del p.K67del | In Frame Del (DEL) | VAF 4/27 reads (15%) | catalogued as rs763080928; called by pindel, varscan2
- CFAP46 | c.292T>C p.S98P | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV63951546; called by muse, mutect2
- CFAP47 | c.320A>T p.Y107F | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.966); catalogued as COSV52885293; called by muse, mutect2, varscan2
- CFAP47 | c.618C>A p.F206L | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV52885333; called by muse, mutect2, varscan2
- CFAP65 | c.5209A>G p.S1737G | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV58561689; called by muse, mutect2
- CFAP92 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs375148155; called by mutect2, varscan2
- CFAP92 | c.191C>A p.T64N | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV54047601; called by muse, mutect2
- CFHR4 | c.1253T>C p.L418S (on ENST00000367416 / NM_001201551.2; = p.L172S on NM_006684.5) | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52229587; called by muse, mutect2
- CHAD | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV51972720; called by muse, mutect2
- CHAF1B | c.827+2T>C p.X276_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV58440227; called by muse, mutect2, varscan2
- CHD1L | c.2608A>G p.T870A | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV63614150; called by muse, mutect2, varscan2
- CHD2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs770105179, COSV59119530, COSV59120561; called by mutect2, varscan2
- CHD3 | c.5786C>T p.P1929L (on ENST00000330494 / NM_001005273.3; = p.P1895L on NM_005852.4) | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs561278276, COSV57875301; called by muse, mutect2, varscan2
- CHD4 | c.4088A>G p.D1363G (on ENST00000357008 / NM_001363606.2; = p.D1376G on NM_001273.5) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58902040; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 78/364 reads (21%) | catalogued as rs1322050057; called by mutect2, pindel, varscan2
- CHD5 | c.5003A>T p.D1668V | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.051); catalogued as COSV52415752, COSV52419236; called by muse, mutect2, varscan2
- CHD6 | c.5714A>G p.N1905S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64691238; called by muse, mutect2
- CHD6 | c.2743C>T p.R915C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58557654; called by muse, mutect2, varscan2
- CHD7 | c.5741G>A p.R1914H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71109966; called by muse, mutect2, varscan2
- CHD8 | c.6667T>C p.S2223P (on ENST00000646647 / NM_001170629.2; = p.S1944P on NM_020920.4) | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV63036902; called by muse, mutect2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 21/120 reads (18%) | catalogued as rs757716680, COSV54024545; called by mutect2*, varscan2
- CHFR | c.1135A>G p.M379V (on ENST00000432561 / NM_001161345.1; = p.M338V on NM_018223.2) | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs377225060; called by muse, varscan2
- CHGB | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66760693; called by muse, mutect2
- CHIT1 | c.1203A>C p.K401N | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55147172; called by muse, mutect2
- CHML | c.217A>T p.T73S | Missense Mutation (SNP) | VAF 18/269 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV59364630; called by muse, mutect2
- CHPT1 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57533594; called by muse, varscan2
- CHRDL1 | c.677G>A p.R226Q (on ENST00000372045; = p.R232Q on NM_145234.4) | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.968); catalogued as rs141240795, COSV54323868, COSV54325580; called by muse, mutect2, varscan2
- CHRM1 | c.815A>C p.Y272S | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.308); catalogued as COSV61006827; called by muse, mutect2, varscan2
- CHRNB4 | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55716242; called by muse, mutect2, varscan2
- CHRNG | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.014); catalogued as COSV51320168; called by muse, mutect2, varscan2
- CHST11 | c.704T>A p.V235D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57988352; called by muse, mutect2, varscan2
- CHST2 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58885684; called by muse, mutect2, varscan2
- CHST8 | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.123); catalogued as COSV52855822; called by mutect2, varscan2
- CHSY1 | c.995T>C p.I332T | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV54253583; called by muse, mutect2
- CIITA | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60857503; called by muse, mutect2, varscan2
- CIP2A | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as rs1559702826, COSV55419053; called by mutect2, varscan2
- CISH | c.572C>T p.A191V (on ENST00000348721 / NM_145071.4; = p.A208V on NM_013324.6) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs764779412, COSV62294960; called by muse, mutect2, varscan2
- CKAP4 | c.1397A>T p.D466V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.165); catalogued as COSV65172667; called by muse, mutect2
- CKMT1A | c.1175A>G p.Y392C | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs576825012, COSV63256897; called by mutect2, varscan2
- CKMT2 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as rs148114477; called by muse, mutect2, varscan2
- CLASRP | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); catalogued as rs753553785, COSV55516593; called by mutect2, varscan2
- CLCN2 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.54); catalogued as COSV55601467; called by muse, mutect2
- CLCN3 | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV61627271; called by muse, mutect2, varscan2
- CLDN18 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1225377853, COSV51736661; called by muse, mutect2
- CLEC14A | c.455T>A p.V152D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV60562732; called by muse, mutect2, varscan2
- CLEC16A | c.2431G>T p.G811C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55489997; called by muse, mutect2
- CLEC4G | c.845A>C p.K282T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV61003404; called by mutect2, varscan2
- CLEC7A | c.379T>C p.Y127H (on ENST00000304084 / NM_197947.3; = p.Y81H on NM_022570.5) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53722471; called by muse, mutect2, varscan2
- CLGN | c.1522del p.T508Pfs*12 | Frame Shift Del (DEL) | VAF 25/119 reads (21%) | catalogued as rs1217577246; called by mutect2, pindel, varscan2
- CLIC1 | c.186del p.Q63Sfs*37 | Frame Shift Del (DEL) | VAF 31/164 reads (19%) | catalogued as rs1562198429; called by mutect2, pindel, varscan2
- CLIC5 | c.731T>A p.V244D (on ENST00000185206 / NM_001370649.1; = p.V85D on NM_016929.5) | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51755114, COSV51759604; called by muse, mutect2
- CLIP2 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.758); catalogued as COSV56279845; called by muse, mutect2
- CLK3 | c.1066del p.I356Sfs*14 (on ENST00000395066 / NM_001130028.1; = p.I208Sfs*14 on NM_003992.4) | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs1272725768; called by pindel, varscan2
- CLSTN3 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as COSV56936676; called by muse, mutect2, varscan2
- CLU | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs1446623022, COSV57066892; called by muse, mutect2, varscan2
- CLUH | c.909A>G p.K303= (on ENST00000435359; = p.K341= on NM_015229.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 10/45 reads (22%) | catalogued as COSV70928827; called by muse, mutect2, varscan2
- CLUH | c.397C>T p.R133C (on ENST00000435359; = p.R171C on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV70928511; called by muse, mutect2, varscan2
- CMIP | c.1727C>T p.A576V (on ENST00000537098 / NM_198390.2; = p.A482V on NM_030629.3) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV67698514; called by muse, mutect2, varscan2
- CMTM7 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1450522711, COSV58550917; called by muse, varscan2
- CMYA5 | c.5621C>A p.P1874H | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.533); catalogued as COSV71406266; called by muse, mutect2
- CNGA1 | c.1255T>C p.F419L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV62054526; called by muse, mutect2
- CNGA2 | c.871T>C p.C291R | Missense Mutation (SNP) | VAF 18/277 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61704767; called by muse, mutect2
- CNIH3 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV55276034; called by muse, mutect2
- CNNM2 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV63995969; called by muse, mutect2, varscan2
- CNNM3 | c.1304T>A p.V435D | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59709284; called by muse, mutect2
- CNNM3 | c.1654A>G p.S552G | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV59709290; called by muse, mutect2, varscan2
- CNST | c.612G>T p.E204D | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63620478; called by muse, mutect2
- CNTLN | c.2452C>T p.R818* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as rs754809834, COSV52072643; called by muse, mutect2, varscan2
- CNTN1 | c.1831A>G p.R611G | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.83); catalogued as COSV61640266; called by muse, mutect2
- CNTN2 | c.1307T>A p.I436N | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV59350267; called by muse, mutect2, varscan2
- CNTN3 | c.610A>C p.N204H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV55172962; called by muse, mutect2, varscan2
- CNTN6 | c.121T>A p.L41I | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV63163487, COSV63174105; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP1 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs962698963, COSV52850921; called by muse, varscan2
- CNTNAP2 | c.2623A>G p.T875A | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV62188505; called by muse, mutect2
- CNTNAP5 | c.2725C>T p.Q909* | Nonsense Mutation (SNP) | VAF 25/129 reads (19%) | catalogued as COSV70488468; called by muse, mutect2, varscan2
- CNTROB | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.443); catalogued as COSV66608299; called by muse, mutect2
- COBL | c.2236G>T p.G746C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV54347305; called by mutect2, varscan2
- COBL | c.2030A>T p.N677I | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV54347317; called by muse, mutect2, varscan2
- COG1 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV55429982; called by muse, mutect2, varscan2
- COG2 | c.1083G>T p.Q361H | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV64187112; called by muse, mutect2
- COG3 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs1398479812, COSV63072882; called by muse, mutect2
- COL11A2 | c.4675C>T p.R1559W (on ENST00000341947 / NM_080680.3; = p.R1452W on NM_080679.2) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); catalogued as rs370966667; ClinVar: uncertain significance; called by muse, varscan2
- COL12A1 | c.9077del p.P3026Lfs*51 | Frame Shift Del (DEL) | VAF 16/141 reads (11%) | catalogued as rs1243039688; called by mutect2, varscan2
- COL12A1 | c.2474C>A p.P825H | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as COSV59397052; called by muse, mutect2
- COL17A1 | c.1234A>T p.T412S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV62227062; called by muse, mutect2, varscan2
- COL18A1 | c.1435G>A p.V479I (on ENST00000359759 / NM_130444.3; = p.V244I on NM_030582.4) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs532978021, COSV62702400; called by muse, mutect2, varscan2
- COL1A1 | c.4024G>T p.G1342C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV56805651; called by mutect2, varscan2
- COL20A1 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV58918178; called by muse, mutect2
- COL21A1 | c.496T>C p.F166L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55164919; called by muse, mutect2
- COL26A1 | c.823C>T p.L275F (on ENST00000313669 / NM_001278563.3; = p.L273F on NM_133457.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV58125293; called by muse, mutect2, varscan2
- COL2A1 | c.4388T>C p.I1463T | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs748077700, COSV56742812; ClinVar: uncertain significance; called by mutect2, varscan2
- COL4A4 | c.2785C>T p.P929S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.208); catalogued as COSV61632690; called by mutect2, varscan2
- COL5A1 | c.4043G>C p.G1348A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1060502252, COSV65665157; ClinVar: uncertain significance; called by mutect2, varscan2
- COL5A2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.047); catalogued as COSV66410253; called by muse, mutect2, varscan2
- COL6A2 | c.2200C>T p.R734C | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886038496, COSV56006569; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A3 | c.2870A>G p.D957G | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.239); catalogued as rs116294003, COSV55091827; called by muse, mutect2, varscan2
- COL6A6 | c.92del p.L31Wfs*16 | Frame Shift Del (DEL) | VAF 40/213 reads (19%) | catalogued as COSV100650165; called by mutect2, pindel, varscan2
- COL6A6 | c.1715T>C p.I572T | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV62026616; called by muse, mutect2
- COL6A6 | c.3747A>C p.K1249N | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as COSV62026628, COSV62033629; called by muse, mutect2, varscan2
- COL6A6 | c.6478A>G p.K2160E | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV62026665; called by muse, mutect2
- COL7A1 | c.5462G>A p.G1821D | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60395942; called by muse, mutect2, varscan2
- COLEC12 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1359684351, COSV68369872; called by muse, mutect2
- COPA | c.1833A>G p.V611= | Splice Region (SNP) | VAF 14/136 reads (10%) | catalogued as rs1434130898, COSV54103392; called by muse, varscan2
- COPB1 | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV51448630; called by muse, mutect2
- COPS3 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs773256226, COSV52005666; called by muse, mutect2, varscan2
- COQ8A | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); catalogued as COSV64657892; called by muse, mutect2, varscan2
- CORIN | c.1618T>C p.C540R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs921554407, COSV56692308; called by muse, mutect2
- CORO6 | c.182T>A p.V61D | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52173188; called by muse, mutect2
- COX4I2 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs373809337, COSV65781791; called by muse, varscan2
- CPA6 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV52730906; called by muse, mutect2, varscan2
- CPAMD8 | c.5477C>T p.P1826L (on ENST00000651564; = p.P1779L on NM_015692.5) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV50185333; called by muse, mutect2
- CPAMD8 | c.1814G>A p.R605H (on ENST00000651564; = p.R558H on NM_015692.5) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as rs1035994038, COSV52232222, COSV52232821; called by mutect2, varscan2
- CPB2 | c.75-1G>A p.X25_splice | Splice Site (SNP) | VAF 14/142 reads (10%) | catalogued as COSV51674820; called by muse, mutect2
- CPD | c.4102A>G p.T1368A | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.217); catalogued as COSV56713384; called by muse, mutect2
- CPEB1 | c.425C>T p.A142V (on ENST00000617958; = p.A82V on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); catalogued as rs374422926, COSV99917351; called by muse, mutect2
- CPEB2 | c.2035-1G>A p.X679_splice | Splice Site (SNP) | VAF 5/73 reads (7%) | catalogued as COSV52592145; called by muse, mutect2
- CPNE1 | c.116del p.G39Afs*43 (on ENST00000352393; = p.G44Afs*43 on NM_003915.5) | Frame Shift Del (DEL) | VAF 19/99 reads (19%) | catalogued as rs752095650; called by pindel, varscan2
- CPO | c.574A>G p.S192G | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV55939951; called by muse, mutect2
- CPT2 | c.493A>T p.T165S | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.072); catalogued as COSV53759468; called by muse, mutect2, varscan2
- CPXM1 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs776351140, COSV66045544; called by muse, mutect2, varscan2
- CR1 | c.3710C>T p.S1237F | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV65458616; called by muse, mutect2, varscan2
- CRBN | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV51641170; called by muse, varscan2
- CREB1 | c.370C>T p.R124* (on ENST00000432329 / NM_134442.5; = p.R110* on NM_004379.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV62064985; called by muse, mutect2, varscan2
- CREB3L2 | c.854T>C p.L285S | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57795575; called by muse, mutect2
- CREB3L3 | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99313876; called by muse, mutect2, varscan2
- CREBBP | c.6431C>T p.A2144V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as rs1254533716, COSV52125523; called by muse, mutect2
- CRHR2 | c.1136A>G p.D379G | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV59265572; called by muse, mutect2
- CRIM1 | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.386); catalogued as COSV54864997; called by muse, mutect2, varscan2
- CRNKL1 | c.1921A>G p.T641A | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV66105983; called by muse, mutect2, varscan2
- CRNKL1 | c.897G>A p.W299* | Nonsense Mutation (SNP) | VAF 18/96 reads (19%) | catalogued as COSV55631467; called by muse, mutect2, varscan2
- CRP | c.487A>T p.N163Y | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV54813674; called by muse, mutect2
- CRTC1 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV58719344; called by muse, mutect2, varscan2
- CRTC2 | c.818del p.G273Afs*29 | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | catalogued as rs771895874; called by mutect2, pindel, varscan2
- CRYBG2 | c.3764T>A p.I1255N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57486326; called by muse, mutect2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | catalogued as rs747248693; called by mutect2, varscan2
- CRYBG3 | c.6290A>T p.D2097V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51712349; called by muse, mutect2
- CRYGC | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs544008612, COSV52204963; called by mutect2, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 17/109 reads (16%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSMD1 | c.8841T>A p.C2947* (on ENST00000520002; = p.C2946* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 28/248 reads (11%) | catalogued as COSV59330857; called by muse, varscan2
- CSMD2 | c.8396G>A p.S2799N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as rs781052117, COSV53917246; called by mutect2, varscan2
- CSMD2 | c.8005C>T p.R2669C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs756852200, COSV53917262; called by mutect2, varscan2
- CSNK1G3 | c.959A>T p.D320V | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV62054830; called by muse, mutect2
- CSPG5 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460266028, COSV53131454; called by muse, mutect2
- CSPP1 | c.2930C>A p.P977H (on ENST00000676605; = p.P936H on NM_024790.6) | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as COSV51585251; called by muse, mutect2
- CT83 | c.319T>C p.S107P | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV64141078; called by muse, mutect2
- CTBP2 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58334574; called by muse, mutect2, varscan2
- CTDSP1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV56090013; called by muse, mutect2, varscan2
- CTIF | c.954dup p.P319Afs*4 | Frame Shift Ins (INS) | VAF 14/123 reads (11%) | catalogued as rs767985178; called by mutect2, pindel
- CTNNB1 | c.451del p.R151Vfs*6 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | catalogued as COSV62691474; called by mutect2, pindel, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CTNND2 | c.3187C>T p.R1063C | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1561136061, COSV58892661; called by muse, mutect2, varscan2
- CTSA | c.990del p.C331Afs*36 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs758642867; called by mutect2, varscan2
- CTSE | c.1130A>G p.D377G (on ENST00000360218; = p.D372G on NM_001910.4) | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1168070557, COSV63060861; called by muse, mutect2
- CTTNBP2 | c.1985T>C p.I662T | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs765681195, COSV50405607; called by muse, mutect2, varscan2
- CUL1 | c.2309A>G p.D770G | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57389139; called by muse, mutect2
- CUL5 | c.188A>G p.Q63R | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV67609014; called by muse, mutect2, varscan2
- CUL9 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52729250; called by muse, mutect2
- CUL9 | c.4621A>G p.T1541A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV52729280; called by muse, mutect2, varscan2
- CXCL16 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV52642059; called by muse, mutect2, varscan2
- CXCR1 | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1467782389, COSV55282081; called by muse, mutect2
- CXCR2 | c.57T>A p.D19E | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV59280850; called by muse, mutect2, varscan2
- CXCR2 | c.489A>C p.K163N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV59280857; called by muse, mutect2
- CYBB | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as rs868992616, CD012000, CD044971, COSV66084754; called by muse, mutect2, varscan2
- CYFIP1 | c.3517C>T p.R1173C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs374943727; called by muse, mutect2, varscan2
- CYP2A13 | c.161T>A p.M54K | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs753562096, COSV57838083; called by mutect2, varscan2
- CYSLTR1 | c.657del p.K219Nfs*3 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs35745545; called by pindel, varscan2
- CYTH4 | c.432C>T p.L144= | Splice Region (SNP) | VAF 8/64 reads (13%) | catalogued as COSV50632796; called by muse, mutect2
- CYTH4 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs1219966516, COSV50631485; called by muse, mutect2, varscan2
- CYYR1 | c.212T>G p.V71G | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54832726; called by muse, mutect2
- D2HGDH | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.513); catalogued as rs747460885, COSV58321070; called by mutect2, varscan2
- DAB1 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs867203792, COSV59724302, COSV59728544; called by muse, mutect2, varscan2
- DAB2 | c.1905T>G p.D635E | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV57914798; called by muse, mutect2
- DAB2 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1400908467, COSV57915017; called by muse, mutect2, varscan2
- DACT1 | c.1505T>C p.V502A | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV60021117; called by muse, mutect2
- DAPL1 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs751618257, COSV59354592; called by mutect2, varscan2
- DBF4 | c.421T>A p.L141I | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.278); catalogued as COSV55997001; called by muse, mutect2
- DCAF12L2 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV63580722, COSV63582449, COSV63583358; called by muse, mutect2
- DCAF12L2 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63581327, COSV63582472; called by muse, mutect2, varscan2
- DCAF16 | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.025); catalogued as COSV66384236; called by muse, mutect2, varscan2
- DCAF16 | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.336); catalogued as COSV66384239; called by muse, mutect2
- DCAF17 | c.995T>A p.I332N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV59830395; called by muse, mutect2
- DCBLD2 | c.2143T>C p.Y715H | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV54581700; called by muse, mutect2, varscan2
- DCDC1 | c.3638A>T p.H1213L (on ENST00000597505 / NM_001367979.1; = p.H320L on NM_020869.3) | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.261); catalogued as COSV100337863; called by muse, mutect2
- DCHS1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs369236555; called by muse, mutect2, varscan2
- DCLK3 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs566457747, COSV69363320, COSV69364181; called by muse, mutect2, varscan2
- DCN | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775666283, COSV50006653; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCP1B | c.1849A>G p.M617V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs749065205, COSV54969253; called by mutect2, varscan2
- DCP1B | c.278T>A p.F93Y | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54969274; called by muse, mutect2, varscan2
- DCTN4 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV69782289; called by muse, varscan2
- DDC | c.1145T>C p.V382A | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV63565388; called by muse, mutect2
- DDHD1 | c.243T>A p.H81Q (on ENST00000323669; = p.H312Q on NM_030637.3) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60359769; called by muse, mutect2, varscan2
- DDHD2 | c.1079T>A p.I360N | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV68157970; called by muse, mutect2
- DDI1 | c.692T>C p.I231T | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs1410770310, COSV56379836; called by muse, mutect2
- DDIT4L | c.517G>T p.G173* | Nonsense Mutation (SNP) | VAF 28/114 reads (25%) | catalogued as COSV56767406, COSV99913794; called by muse, varscan2
- DDX10 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV59435283; called by muse, mutect2, varscan2
- DDX23 | c.2440C>T p.R814W | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56398638; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 24/83 reads (29%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX46 | c.1704G>T p.E568D | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as COSV62799497; called by muse, mutect2
- DDX5 | c.1490A>G p.Y497C | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as rs1161502195, COSV56749300; called by muse, mutect2, varscan2
- DDX60 | c.3508G>A p.A1170T | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV67096982; called by muse, varscan2
- DDX60 | c.3427G>A p.A1143T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV67096987; called by muse, varscan2
- DEAF1 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58607300; called by muse, mutect2, varscan2
- DENND1A | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs751689270, COSV65350832; called by muse, mutect2, varscan2
- DENND1C | c.569G>T p.R190M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67373543; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs553532837; called by mutect2, varscan2
- DENND4B | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1207258982, COSV63409091; called by muse, mutect2
4,264 further variants in this file (3,043 protein-altering or splice-affecting, 1,113 silent, 108 other) are not listed here.
